CCDI case PBBTKZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/19a99f0c-7635-40db-b0ed-92f69a84317e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (5,974 days).

Biospecimens (3 samples)
- Sample 0DH3KD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH3KV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH3LH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
